Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A496, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A496-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

DIAGNOSIS

PARTIAL LIVER RESECTION (SEGMENTS 5 AND 6) WITH GALLBLADDER AND CYSTIC DUCT:

1. Hepatocellular carcinoma, grade 2 of 3, forming an 11.5 cm mass (see staging parameters for details)
2. Background liver without diagnostic abnormality
3. Resection margins free of tumor
4. Gallbladder and cystic duct without diagnostic abnormality

2010 LIVER HEPATOCELLULAR CANCER STAGING PARAMETERS

Case number: [REDACTED] Patient name: [REDACTED]

Final TNM: pT1NXM0
stage: I

MACROSCOPIC

SPECIMEN TYPE

Segmentectomies
Segments 5 and 6

TUMOR TYPE

Single without satellites

TUMOR SIZE

11.5 X 8 X 7 cm

ICD-O-3

Carcinoma, hepatocellular, NOS
8170/3

Site: liver C22.0

9-7-12 ED

MICROSCOPIC

HISTOLOGIC TYPE

Hepatocellular carcinoma

HISTOLOGIC GRADE

Nuclear grade 2 of 3 (Lauwers grade)

MARGINS

Uninvolved by tumor
Distance to nearest margin is 1 cm

LIVER CAPSULE

No tumor present

LYMPHATIC/VASCULAR INVASION

Absent: Lymph-vascular invasion not present/Not identified

TUMOR EXTENSION

Tumor confined to liver

MITOTIC ACTIVITY

2.5/10 HPF

HEPATOCELLULAR PROGNOSTIC INDEX

Fair prognosis - Grade 2 without vascular invasion

PATHOLOGIC STAGING

EXTENT OF INVASION

pT1. (Solitary tumor without vascular invasion)

[page 2 of 3]
REGIONAL LYMPH NODES

pNX. (Cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT1NXM0

stage: I

** The pathologic stage presumes no distant metastasis.

PROGNOSTIC FACTORS (SITE SPECIFIC FACTORS)

CIRRHOSIS

Absent

SMALL CELL DYSPLASIA

Absent

FIBROSIS SCORE

0

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

History of hepatocellular carcinoma

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Partial liver resection, section 5 and 6, frozen for margin
The specimen is received fresh from the OR labeled "partial liver resection, sections 5 and 6 - frozen for margin." It consists of a 520 gram, 14 x 9.8 x 7.5 cm partial liver resection. The smooth capsular surface displays an 11.5 x 8 x 7 cm bosselated tan tumor bulging from its external surface. The margin is inked blue and the tissue is serially cross sectioned.

INTRAOPERATIVE PATHOLOGY CONSULTATION: "Tumor grossly 1 cm from cauterized margin" is rendered by [REDACTED]

The tumor has variegated, lobulated, yellow, tan, pink and brown cut surfaces with predominantly well-defined edges. The tumor grossly abuts the gallbladder bed. Extension through the capsule and into the gallbladder bed is not seen. No other lesions are seen on the red-brown hepatic parenchyma.

The attached 8.7 cm in length and 3 cm in diameter intact distended gallbladder has smooth glistening serosal surfaces which are mildly edematous. Received within the gallbladder lumen are numerous 0.8 cm in average diameter dark green, black multifaceted choleliths aggregating to 6.5 x 4.5 x 0.7 cm. On opening the mucosa displays two components. One component extending to the cystic duct margin for a length of 2 cm is red-tan and velvety. The remaining component of the mucosa is pink-tan, flat to velvety with a slightly thickened wall up to 0.2-0.3 cm thick and measuring approximately 1.8 cm in greatest dimension. The remaining mucosa at the body and fundus is tan with thin trabeculations.

Representative sections are submitted in eight cassettes labeled:

- 1-2. Liver tumor with closest blue-inked margin
- 3-4. Tumor with adjacent hepatic parenchyma
- 5-6. Tumor with capsule
7. Gallbladder neck at the transition of thickened wall to relatively normal-appearing wall at the cystic duct
8. En face cystic duct margin, and fundic wall

[page 3 of 3]
[REDACTED]

Note: The gross specimen was photographed. A portion of the tumor, paranormal and normal parenchyma were banked for possible ancillary study.

This case is accessioned in

Gross dictation by: [REDACTED]

MICROSCOPIC

The microscopic appearance substantiates the diagnosis. Dictation by:
transcribed by:

Interpreted at

COLLECTED:

ACCESSIONED:

SIGNED:

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]
Information

Lab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]
Report

Order Result History

Lab Status
Order Complete [3]

Result Information

Result Date and Time

Status
Final result

Provider Status
Ordered

Lab Information

Order Details

Parent Order ID

Child Order ID
[REDACTED]

Entry Date

Specimen Information

Specimen Source
Other

Collection Date

Collection Time

Audit Trail

Action
Order Printed
Order Printed

User
[REDACTED]

Date/Time

MyChart Status:

This result is currently not released to

Order

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]

hw 8/30/12

Source: NCI Genomic Data Commons file 54953923-8c7c-4bf4-bc24-d3495366de0f (TCGA-FV-A496.358A0018-5731-45D3-97B8-502A3BF95FA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).